Somatic mutation profile of tumor specimen TCGA-17-Z051-01A (aliquot TCGA-17-Z051-01A-01W-0747-08) from TCGA case TCGA-17-Z051, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z051-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8ea005c-2de0-4bb8-8009-cfab900cb0fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z051-11A (Solid Tissue Normal), aliquot TCGA-17-Z051-11A-01W-0747-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5e20ce6-6a51-4bcb-b383-5758bebf7030

The open-access MAF lists 143 somatic variants for this specimen: 113 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 28, Nonsense Mutation 6, Frame Shift Del 5, Splice Site 4, Splice Region 3, 3'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 37/52 reads (71%) | hotspot (GDC flag); catalogued as rs121913300, CM941205, COSV57297576, COSV57321266; ClinVar: pathogenic; called by mutect2, varscan2
- ADGRG6 | c.2320A>G p.I774V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.83); PolyPhen benign (0.194); catalogued as COSV51602807; called by muse, mutect2, varscan2
- ARL8A | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as rs769466486; called by muse, mutect2, varscan2
- ARNTL2 | c.1586G>A p.R529K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as COSV99667765; called by muse, mutect2, varscan2
- ARSF | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs148764513, COSV63839074; called by muse, mutect2, varscan2
- ARSH | c.1672C>T p.L558F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.12); catalogued as COSV101140014; called by mutect2, varscan2
- BATF2 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV57249465; called by muse, mutect2, varscan2
- CDH18 | c.2161G>T p.A721S | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.134); catalogued as COSV56936228, COSV56953994; called by muse, mutect2, varscan2
- CLDN11 | c.508G>T p.V170L | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753528742; called by mutect2, varscan2
- CUL1 | c.1214A>G p.N405S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs772237633; called by muse, mutect2, varscan2
- EMD | c.677G>T p.W226L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM960512; called by muse, mutect2
- EYA3 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100870244; called by muse, mutect2
- FLG | c.1351C>A p.Q451K | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.766); catalogued as COSV64236048; called by muse, mutect2, varscan2
- GABRG3 | c.214G>T p.V72L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.273); catalogued as COSV61518492; called by muse, mutect2, varscan2
- GALNT17 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100352565; called by muse, varscan2
- GJA9 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 86/493 reads (17%) | catalogued as rs769442681, COSV62532507; called by muse, mutect2, varscan2
- H2BC1 | c.317del p.G106Efs*27 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | catalogued as COSV51236811; called by mutect2, pindel, varscan2
- IRS4 | c.3088G>T p.A1030S | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV64533145; called by muse, varscan2
- ITIH2 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs144713735; called by muse, mutect2, varscan2
- MAGEE1 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV63909246; called by muse, mutect2, varscan2
- MOV10L1 | c.2073T>C p.N691= | Splice Region (SNP) | VAF 26/59 reads (44%) | catalogued as rs1189887397; called by muse, mutect2, varscan2
- NAV2 | c.2683A>G p.K895E (on ENST00000396087 / NM_001244963.2; = p.K872E on NM_145117.5) | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1247221378; called by muse, mutect2, varscan2
- NEB | c.12126T>G p.N4042K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1304618869; called by muse, mutect2, varscan2
- NEXMIF | c.1501G>T p.G501C | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs747796062; called by muse, mutect2, varscan2
- OR10G9 | c.727del p.H243Tfs*17 | Frame Shift Del (DEL) | VAF 60/190 reads (32%) | catalogued as COSV66686390; called by pindel, varscan2
- OR10J3 | c.541G>T p.D181Y | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59955535; called by muse, mutect2, varscan2
- OR6M1 | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.734); catalogued as COSV58433973; called by muse, mutect2, varscan2
- PCDH9 | c.3002G>T p.G1001V | Missense Mutation (SNP) | VAF 54/70 reads (77%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as rs576798095, COSV100118063; called by muse, mutect2, varscan2
- PCDHGA3 | c.2227G>T p.A743S | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV53951173; called by muse, mutect2, varscan2
- PIM2 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.051); catalogued as rs782551073, COSV55946255; called by muse, mutect2, varscan2
- PKD1L1 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs778661029; called by muse, mutect2, varscan2
- POLG | c.2465C>T p.P822L | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1012514400; called by muse, varscan2
- PTH1R | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57317617; called by mutect2, varscan2
- PTPRF | c.2576G>T p.R859L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs567638313; called by muse, mutect2, varscan2
- REG1B | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs141167987; called by muse, varscan2
- RIF1 | c.3248A>G p.Y1083C | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754076811; called by muse, mutect2, varscan2
- RSPRY1 | c.1247C>G p.P416R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as rs756616961; called by muse, varscan2
- SCML2 | c.1043G>C p.G348A | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.218); catalogued as COSV52620043; called by muse, mutect2, varscan2
- SOX3 | c.408G>T p.Q136H | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV65168330; called by muse, varscan2
- TRIM71 | c.2556C>A p.D852E | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT tolerated (0.19); PolyPhen benign (0.259); catalogued as COSV67472687; called by muse, varscan2
- ZBTB32 | c.1258C>A p.L420M | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV99386405; called by muse, mutect2, varscan2
- ZNF667 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 117/474 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs202093161, COSV52630823, COSV52631642; called by muse, mutect2, varscan2
- ZNF681 | c.1745G>A p.R582K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV68073987; called by muse, mutect2, varscan2
- ABCC11 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ABCC12 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by mutect2, varscan2
- ACKR3 | c.970T>C p.Y324H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADCY7 | c.589_590delinsG p.H197Afs*17 | Frame Shift Del (DEL) | VAF 25/54 reads (46%) | called by pindel, varscan2*
- AHNAK2 | c.7339C>A p.P2447T | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- AP2M1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- APBB1IP | c.627G>T p.E209D | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- APEX2 | c.479C>A p.A160E | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARID5B | c.2825T>G p.V942G | Missense Mutation (SNP) | VAF 55/320 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, varscan2
- ATP10D | c.743C>A p.P248Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRIP1 | c.1368dup p.V457Cfs*6 | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- CALCR | c.979-2A>G p.X327_splice (on ENST00000649521 / NM_001164737.2; = p.X311_splice on NM_001742.4) | Splice Site (SNP) | VAF 39/76 reads (51%) | called by muse, mutect2, varscan2
- CARD10 | c.1874G>C p.G625A | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHAT | c.933+1G>T p.X311_splice | Splice Site (SNP) | VAF 7/9 reads (78%) | called by muse, mutect2, varscan2
- CLRN1 | c.36G>T p.M12I | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- COL9A1 | c.2311C>A p.Q771K | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- COLEC12 | c.1106C>A p.T369N | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CTAGE6 | c.1034T>C p.V345A | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DAGLA | c.2314G>T p.A772S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DBX2 | c.854A>T p.Q285L | Missense Mutation (SNP) | VAF 56/281 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- EFCAB7 | c.683-1G>C p.X228_splice | Splice Site (SNP) | VAF 78/228 reads (34%) | called by muse, mutect2, varscan2
- EMILIN1 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ENPP3 | c.1359C>A p.N453K | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ERCC6 | c.1171del p.A391Qfs*14 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- GAD1 | c.546A>T p.T182= | Splice Region (SNP) | VAF 44/99 reads (44%) | called by muse, mutect2, varscan2
- GIPR | c.1197G>T p.V399= | Splice Region (SNP) | VAF 28/44 reads (64%) | called by muse, mutect2, varscan2
- GJA9 | c.1387C>G p.Q463E | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- IRS4 | c.1240C>A p.L414M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KIAA1109 | c.12706A>G p.M4236V | Missense Mutation (SNP) | VAF 83/110 reads (75%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by mutect2, varscan2
- KRT32 | c.468+1G>A p.X156_splice | Splice Site (SNP) | VAF 5/41 reads (12%) | called by mutect2, varscan2
- LMLN | c.1774A>T p.N592Y | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by mutect2, varscan2
- LVRN | c.2456C>A p.P819H | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MECOM | c.1441G>T p.A481S (on ENST00000468789 / NM_001105078.4; = p.A669S on NM_004991.4) | Missense Mutation (SNP) | VAF 76/357 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MLKL | c.189C>A p.N63K | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.99); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MYO18B | c.752C>T p.T251I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYOZ1 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- NRXN3 | c.557C>A p.T186N (on ENST00000557594 / NM_001272020.2; = p.T818N on NM_004796.6) | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by mutect2, varscan2
- NUDT13 | c.185C>G p.S62* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- NUP93 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2
- OR56A4 | c.923C>G p.T308R | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR5L1 | c.493A>G p.R165G | Missense Mutation (SNP) | VAF 151/341 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAPSS2 | c.1708C>T p.H570Y | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- PGRMC1 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLG | c.2464C>G p.P822A | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, varscan2
- PPIE | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PRICKLE1 | c.1946A>T p.Q649L | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1324G>T p.G442* (on ENST00000421990 / NM_001136042.2; = p.G424* on NM_025267.3) | Nonsense Mutation (SNP) | VAF 54/164 reads (33%) | called by muse, varscan2
- PTH | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RAC2 | c.290G>A p.W97* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- RPGR | c.2876T>C p.V959A (on ENST00000339363 / NM_001367249.1; = p.V754A on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- SH3BGRL | c.341C>A p.A114E | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHROOM3 | c.4027G>T p.V1343F | Missense Mutation (SNP) | VAF 61/72 reads (85%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX3 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, varscan2
- SPAG17 | c.3413G>C p.G1138A | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAB3 | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TBC1D24 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- TBX10 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX15 | c.6650C>T p.S2217F (on ENST00000256246; = p.S2600F on NM_001350162.2) | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2
- TEX15 | c.5983C>T p.Q1995* (on ENST00000256246; = p.Q2378* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- TRBV4-1 | c.107A>C p.N36T | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- TTN | c.61184A>C p.Y20395S (on ENST00000591111; = p.Y12971S on NM_003319.4) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TUBB8 | c.391C>A p.Q131K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- TUBGCP5 | c.920A>T p.H307L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by mutect2, varscan2
- WDHD1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- XIAP | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ZC3H11A | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 43/311 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZC3H12B | c.2254A>G p.M752V | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZDHHC6 | c.790del p.D264Ifs*28 | Frame Shift Del (DEL) | VAF 16/110 reads (15%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.4126G>C p.G1376R | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (0.47); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AOC1 | c.1161C>G p.P387= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as COSV62868875; called by muse, mutect2, varscan2
- C2CD3 | c.3321A>T p.G1107= | Silent (SNP) | VAF 41/91 reads (45%) | called by mutect2, varscan2
- CDC42EP1 | c.819C>T p.P273= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, varscan2
- CHRM2 | c.582C>A p.A194= | Silent (SNP) | VAF 61/121 reads (50%) | catalogued as COSV57780665; called by muse, varscan2
- CRYGN | c.171C>T p.F57= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs267601423; called by muse, mutect2, varscan2
- CSF2 | c.87C>A p.P29= | Silent (SNP) | VAF 16/20 reads (80%) | called by muse, mutect2, varscan2
- DSCAML1 | c.5172G>C p.L1724= (on ENST00000321322; = p.L1664= on NM_020693.4) | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as COSV58399200; called by muse, mutect2, varscan2
- ELOA3 | c.1056C>A p.L352= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV55302176, COSV55308222; called by mutect2, varscan2
- GBA | c.624G>A p.Q208= | Silent (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- HDAC6 | c.567C>T p.G189= | Silent (SNP) | VAF 41/169 reads (24%) | called by muse, mutect2, varscan2
- INSM1 | c.864G>T p.S288= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- KIF2B | c.1470T>A p.P490= | Silent (SNP) | VAF 43/115 reads (37%) | called by muse, mutect2, varscan2
- LRRC4B | c.465G>A p.E155= | Silent (SNP) | VAF 33/106 reads (31%) | called by muse, mutect2, varscan2
- MUC17 | c.7104T>A p.P2368= | Silent (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- MXRA5 | c.7089G>A p.V2363= | Silent (SNP) | VAF 37/105 reads (35%) | called by muse, mutect2, varscan2
- NFKB1 | c.1302C>G p.T434= (on ENST00000394820 / NM_001382627.1; = p.T435= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 58/86 reads (67%) | called by muse, varscan2
- NPAS4 | c.1143G>A p.L381= | Silent (SNP) | VAF 45/260 reads (17%) | called by mutect2, varscan2
- RBP3 | c.3279C>A p.P1093= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- SALL4 | c.213G>T p.T71= | Silent (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- SLC11A1 | c.1026C>G p.A342= | Silent (SNP) | VAF 31/136 reads (23%) | called by muse, mutect2, varscan2
- SLC30A6 | c.1206A>C p.L402= | Silent (SNP) | VAF 91/257 reads (35%) | called by muse, mutect2, varscan2
- SLITRK4 | c.1930C>A p.R644= | Silent (SNP) | VAF 103/242 reads (43%) | catalogued as rs782740433, COSV62024129; called by muse, mutect2, varscan2
- THEM5 | c.585C>A p.P195= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV64313104; called by muse, mutect2, varscan2
- TIMM17B | c.78C>A p.I26= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV54431400; called by muse, mutect2, varscan2
- TSGA13 | c.609C>T p.Y203= | Silent (SNP) | VAF 38/301 reads (13%) | called by muse, mutect2, varscan2
- VPS13A | c.4341A>G p.T1447= | Silent (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- ZNF468 | c.825G>A p.E275= | Silent (SNP) | VAF 25/265 reads (9%) | called by muse, mutect2, varscan2
- ZNF638 | c.1533A>T p.P511= | Silent (SNP) | VAF 61/153 reads (40%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445686 G>A | 3'Flank (SNP) | VAF 16/45 reads (36%) | catalogued as rs771269200; called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928761 G>A | 3'Flank (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
